Somatic mutation profile of tumor specimen TCGA-BR-6707-01A (aliquot TCGA-BR-6707-01A-11D-1882-08) from TCGA case TCGA-BR-6707, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 75.4 years (27,529 days).
Specimen TCGA-BR-6707-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d0fb36ab-8173-4899-b5f4-867d2534b70a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-6707-10A (Blood Derived Normal), aliquot TCGA-BR-6707-10A-01D-1882-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7d23874c-fc40-4c6f-8f41-006001d0f6b7

The open-access MAF lists 69 somatic variants for this specimen: 54 protein-altering or splice-affecting, 13 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 13, Nonsense Mutation 9, Frame Shift Del 2, In Frame Del 1, RNA 1, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 45/100 reads (45%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PTEN | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 31/115 reads (27%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs121909229, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABL2 | c.2692C>T p.R898* (on ENST00000502732 / NM_007314.4; = p.R883* on NM_005158.5) | Nonsense Mutation (SNP) | VAF 10/68 reads (15%) | catalogued as rs1226660364, COSV61011488; called by muse, mutect2, varscan2
- ADGRV1 | c.3145G>T p.E1049* | Nonsense Mutation (SNP) | VAF 8/177 reads (5%) | catalogued as COSV67979538; called by muse, mutect2
- AP3B2 | c.1207A>G p.N403D | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.86); catalogued as COSV55606984; called by muse, mutect2
- ATP2B2 | c.1642G>T p.G548C (on ENST00000352432; = p.G514C on NM_001683.5) | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59490771; called by muse, mutect2, varscan2
- BCOR | c.3649C>T p.R1217* (on ENST00000378444 / NM_001123385.2; = p.R1183* on NM_017745.6) | Nonsense Mutation (SNP) | VAF 41/74 reads (55%) | catalogued as CM1313413, COSV60700105, COSV60714720; called by muse, mutect2, varscan2
- CARD11 | c.2719G>A p.E907K | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.036); catalogued as COSV62754269; called by muse, mutect2, varscan2
- CCDC88A | c.5005C>T p.H1669Y (on ENST00000436346 / NM_001365480.1; = p.H1641Y on NM_018084.5) | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.92); PolyPhen benign (0.003); catalogued as COSV55057301; called by muse, mutect2, varscan2
- CPS1 | c.3186C>A p.N1062K | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV51803549; called by muse, mutect2, varscan2
- CRY2 | c.1532C>T p.S511L | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as COSV69888227; called by muse, mutect2, varscan2
- DAGLB | c.2012T>C p.V671A | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV51702615; called by muse, mutect2
- DENND5A | c.2881G>A p.V961I | Missense Mutation (SNP) | VAF 73/402 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as rs1397760393, COSV60231723; called by muse, mutect2, varscan2
- DKK2 | c.310C>T p.R104W | Missense Mutation (SNP) | VAF 45/163 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1379480164, COSV53394626; called by muse, mutect2, varscan2
- ENTPD4 | c.1570G>A p.V524I | Missense Mutation (SNP) | VAF 20/146 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.883); catalogued as COSV62268383; called by muse, mutect2, varscan2
- FLNC | c.6677T>C p.L2226P | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.094); catalogued as COSV57951545; called by muse, mutect2, varscan2
- FRAS1 | c.1630G>T p.E544* | Nonsense Mutation (SNP) | VAF 5/46 reads (11%) | catalogued as COSV53593427; called by mutect2, varscan2
- IGKV3D-11 | c.343C>A p.H115N | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as rs745980240; called by muse, mutect2, varscan2
- INTU | c.2212C>T p.R738W | Missense Mutation (SNP) | VAF 67/263 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.017); catalogued as rs774939551, COSV58869760; called by muse, mutect2, varscan2
- KIF1A | c.1240G>A p.A414T | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.043); catalogued as rs1345536541, COSV57483660; called by muse, mutect2, varscan2
- KL | c.520C>T p.R174W | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV66308035; called by muse, mutect2, varscan2
- LAMB4 | c.4664A>G p.K1555R | Missense Mutation (SNP) | VAF 55/236 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.154); catalogued as COSV52714498; called by muse, mutect2, varscan2
- LARP1 | c.679G>T p.E227* (on ENST00000518297 / NM_033551.3; = p.E150* on NM_015315.5 and 6 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 15/150 reads (10%) | catalogued as COSV60425159; called by muse, mutect2
- LHX4 | c.734C>T p.S245F | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.122); catalogued as COSV55373399, COSV55374823; called by muse, mutect2, varscan2
- MAGED2 | c.443C>G p.A148G | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.039); catalogued as COSV54497095; called by muse, mutect2, varscan2
- MAP1B | c.6025G>T p.E2009* | Nonsense Mutation (SNP) | VAF 66/303 reads (22%) | catalogued as COSV57094668; called by muse, mutect2, varscan2
- MSH4 | c.919G>T p.E307* | Nonsense Mutation (SNP) | VAF 12/41 reads (29%) | catalogued as COSV54197448, COSV54213989; called by muse, mutect2, varscan2
- MYH2 | c.5708G>A p.R1903H | Missense Mutation (SNP) | VAF 50/185 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs770302436, COSV55432703; called by muse, mutect2, varscan2
- N4BP2L2 | c.1213A>T p.I405F | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.496); catalogued as COSV57227519; called by muse, mutect2
- OBSCN | c.2490G>C p.W830C | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV52747095; called by muse, mutect2, varscan2
- OR2T6 | c.773C>T p.T258M | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs141134612; called by muse, mutect2, varscan2
- PLCG2 | c.743G>A p.R248K | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated (0.73); PolyPhen benign (0.384); catalogued as COSV63867762; called by muse, mutect2, varscan2
- PRDM9 | c.365C>A p.A122E | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.206); catalogued as rs773183075, COSV57003315, COSV99691530; called by muse, mutect2, varscan2
- PROX1 | c.1639G>A p.A547T | Missense Mutation (SNP) | VAF 36/149 reads (24%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV54776381; called by muse, mutect2, varscan2
- PSG11 | c.787G>A p.A263T | Missense Mutation (SNP) | VAF 22/251 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0.017); catalogued as rs527275238, COSV60453877; called by muse, mutect2
- RGL1 | c.2077G>A p.A693T (on ENST00000360851 / NM_001297672.2; = p.A728T on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.212); catalogued as rs146832723, COSV58979708; called by muse, mutect2, varscan2
- RIMS2 | c.3653G>A p.R1218Q | Missense Mutation (SNP) | VAF 49/319 reads (15%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.297); catalogued as rs375929179; called by muse, mutect2, varscan2
- RNF217 | c.996C>G p.Y332* (on ENST00000521654 / NM_001286398.2; = p.Y40* on NM_152553.5) | Nonsense Mutation (SNP) | VAF 4/64 reads (6%) | catalogued as COSV51574873, COSV51577777; called by muse, mutect2
- SCRT2 | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.407); catalogued as COSV55728958; called by muse, mutect2, varscan2
- SLC22A1 | c.928G>A p.G310R | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.327); catalogued as COSV61451703; called by muse, mutect2, varscan2
- SLC23A3 | c.866A>T p.E289V (on ENST00000409878 / NM_001144889.2; = p.N257Y on NM_144712.5) | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.239); catalogued as COSV55405764; called by muse, mutect2, varscan2
- SLC46A1 | c.775G>A p.A259T | Missense Mutation (SNP) | VAF 40/193 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.195); catalogued as rs370955621; called by muse, mutect2, varscan2
- SLC4A10 | c.3078_3080del p.L1026del (on ENST00000446997 / NM_001354461.2; = p.L996del on NM_022058.4 and 5 other RefSeq transcripts) | In Frame Del (DEL) | VAF 14/62 reads (23%) | catalogued as rs778147754; called by pindel, varscan2
- SNTG1 | c.1344C>A p.S448R | Missense Mutation (SNP) | VAF 53/230 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as rs1325866719, COSV52428190; called by muse, mutect2, varscan2
- SORT1 | c.1453G>A p.V485I | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.218); catalogued as rs776815822, COSV56664549; called by muse, mutect2, varscan2
- THBS1 | c.1120+1G>A p.X374_splice | Splice Site (SNP) | VAF 16/46 reads (35%) | catalogued as rs539874413, COSV52950388; called by muse, mutect2, varscan2
- TIMELESS | c.926C>T p.S309L | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.079); catalogued as COSV57509430; called by muse, mutect2, varscan2
- TRIM35 | c.466C>T p.R156W | Missense Mutation (SNP) | VAF 72/206 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as rs1198170891, COSV59522411; called by muse, mutect2, varscan2
- TSHZ2 | c.2645G>A p.R882H | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61587202, COSV61590613; called by muse, mutect2, varscan2
- ZNF235 | c.1684C>T p.Q562* | Nonsense Mutation (SNP) | VAF 17/96 reads (18%) | catalogued as COSV52155322; called by muse, mutect2, varscan2
- ZNF569 | c.1396T>C p.Y466H | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV57593960; called by muse, mutect2, varscan2
- ARID1A | c.4875del p.I1625Mfs*10 | Frame Shift Del (DEL) | VAF 48/132 reads (36%) | called by mutect2, pindel, varscan2
- BIRC6 | c.5265_5271del p.G1756Vfs*2 | Frame Shift Del (DEL) | VAF 4/22 reads (18%) | called by mutect2, pindel
- TRAV10 | c.214A>T p.T72S | Missense Mutation (SNP) | VAF 45/135 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ANO3 | c.1512C>T p.I504= | Silent (SNP) | VAF 35/109 reads (32%) | catalogued as rs1220422100, COSV56782510; called by muse, mutect2, varscan2
- EPHB1 | c.1089C>T p.C363= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as COSV67655084, COSV67672344; called by muse, mutect2, varscan2
- GOLGA2 | c.999G>A p.T333= | Silent (SNP) | VAF 7/163 reads (4%) | catalogued as rs997948957, COSV68596960; called by muse, mutect2
- GRSF1 | c.768A>T p.G256= | Silent (SNP) | VAF 29/108 reads (27%) | catalogued as COSV54654742; called by muse, mutect2, varscan2
- LRP1B | c.7824A>G p.A2608= | Silent (SNP) | VAF 19/77 reads (25%) | catalogued as COSV67192003; called by muse, mutect2, varscan2
- MUSK | c.2442C>T p.Y814= | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as rs779578271, COSV51879173; called by muse, mutect2, varscan2
- NLGN4X | c.1545C>T p.N515= | Silent (SNP) | VAF 23/47 reads (49%) | catalogued as rs772619986, COSV52006540; ClinVar: likely benign; called by muse, mutect2, varscan2
- PCDHA12 | c.1362G>A p.A454= | Silent (SNP) | VAF 35/186 reads (19%) | catalogued as COSV56481412; called by muse, mutect2, varscan2
- PCDHB7 | c.1161C>T p.D387= | Silent (SNP) | VAF 16/76 reads (21%) | catalogued as rs781909345, COSV50755569; called by muse, mutect2, varscan2
- PRAME | c.834G>A p.P278= | Silent (SNP) | VAF 33/147 reads (22%) | catalogued as rs548426100, COSV67161100; called by muse, mutect2, varscan2
- RASSF9 | c.408C>T p.N136= | Silent (SNP) | VAF 87/342 reads (25%) | catalogued as COSV63432745; called by muse, mutect2, varscan2
- SETD2 | c.1854A>G p.S618= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV57431589; called by muse, mutect2, varscan2
- TAS2R7 | c.411C>T p.C137= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as rs375435543; called by muse, mutect2, varscan2
- AC024940.1 | n.3233G>A | RNA (SNP) | VAF 20/105 reads (19%) | catalogued as rs752880637; called by muse, mutect2, varscan2
- NETO1 | c.29-350G>C | Intron (SNP) | VAF 6/26 reads (23%) | catalogued as rs1182936262, COSV100198516, COSV55005770; called by muse, mutect2, varscan2
